Gene-level copy-number profile of specimen HCM-BROD-0693-C71-85A from HCMI case HCM-BROD-0693-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.3 years (24,222 days).
Specimen HCM-BROD-0693-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5f7f3ccc-468e-484e-82d7-2a64722d7f0d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0693-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/69f09874-c409-4c2d-9546-78accc346ca7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,655; copy number 2: 44,080; copy number 3: 9,981; copy number 4: 173; copy number 5: 27.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 27 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:53,926,676–54,759,974, 11 genes, copy number 5 (within-gene range 4–5): LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G.
- chr7:83,355,154–83,362,266, 1 gene, copy number 5: AC079799.1.
- chr7:112,328,189–112,521,670, 10 genes, copy number 5 (within-gene range 2–5): AC004112.1, MTND5P8, MTND6P24, MTCYBP24, IFRD1, AC079741.1, AC005192.1, AC079741.2, LSMEM1, NPM1P14.
- chr7:138,460,259–138,701,362, 5 genes, copy number 5 (within-gene range 2–5): TRIM24, RPS3AP28, SVOPL, AC013429.2, AC013429.1.

Autosomal genes at a single copy (total copy number 1): 1,822. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
